Somatic mutation profile of tumor specimen C3N-02592-01 (aliquot CPT0162760006) from CPTAC case C3N-02592, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.8 years (23,318 days).
Specimen C3N-02592-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48cee487-631a-496f-9d13-2ab88f95e4fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02592-31 (Blood Derived Normal), aliquot CPT0162820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dca7db9-01e4-4002-9fb9-5efff9b04228

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 6, Intron 6, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 55/612 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 107/994 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs1565306080, COSV72207675; called by muse, mutect2, varscan2
- ADGRG4 | c.6821C>T p.S2274L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1272460149, COSV54956046; called by muse, mutect2, varscan2
- AHNAK2 | c.4789G>C p.D1597H | Missense Mutation (SNP) | VAF 54/1282 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100318820; called by muse, mutect2
- CAPN15 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs560874988; called by muse, mutect2
- GDAP1L1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs140997304; called by muse, mutect2
- GPR50 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 66/467 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs764731190; called by muse, mutect2, varscan2
- LRP5 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 31/411 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs970458513, CM153251, COSV53723710; called by muse, mutect2
- MYH7 | c.4894G>A p.A1632T | Missense Mutation (SNP) | VAF 47/788 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs565663412, COSV62518371; called by muse, mutect2
- OR1L1 | c.298C>T p.R100C (on ENST00000373686; = p.R50C on NM_001005236.3) | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747195797, COSV58935455; called by muse, mutect2, varscan2
- PCSK6 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs913555936; called by muse, mutect2
- PLA2R1 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs199979054, COSV51775194; called by muse, mutect2
- TAF5L | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs1420132560; called by muse, mutect2
- ABHD8 | c.826A>T p.N276Y | Missense Mutation (SNP) | VAF 18/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ARL4A | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 22/481 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CCDC190 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.117); called by muse, mutect2
- CHST12 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 30/571 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COP1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- CYP2B6 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 56/850 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2
- EXOC2 | c.1750G>C p.V584L | Missense Mutation (SNP) | VAF 40/449 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- FAM221B | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 521/3910 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- FREM3 | c.6346C>A p.P2116T | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GRM1 | c.1280T>C p.M427T | Missense Mutation (SNP) | VAF 53/1036 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HERC1 | c.4279G>T p.V1427F | Missense Mutation (SNP) | VAF 36/870 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2
- MSH5 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 31/354 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- MYO9B | c.1657T>G p.F553V | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NBAS | c.5971T>A p.Y1991N | Missense Mutation (SNP) | VAF 33/498 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- STK38L | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TAOK2 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 30/532 reads (6%) | called by muse, mutect2
- TEX11 | c.325G>A p.E109K (on ENST00000344304; = p.E94K on NM_031276.3) | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.154); called by muse, mutect2
- TMEM8B | c.671C>A p.A224E | Missense Mutation (SNP) | VAF 424/1466 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- WDR26 | c.703T>A p.L235M (on ENST00000414423 / NM_001379403.1; = p.L135M on NM_025160.7) | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP2A1 | c.570G>T p.A190= | Silent (SNP) | VAF 29/555 reads (5%) | called by muse, mutect2
- CACNA1S | c.2964C>T p.R988= | Silent (SNP) | VAF 66/1329 reads (5%) | catalogued as rs778128095, COSV62938764; called by muse, mutect2
- RGMA | c.1071C>T p.Y357= | Silent (SNP) | VAF 31/548 reads (6%) | catalogued as rs372399863; called by muse, mutect2
- TENM4 | c.48C>T p.R16= | Silent (SNP) | VAF 54/483 reads (11%) | catalogued as rs1218746162; called by muse, mutect2, varscan2
- TSPYL6 | c.570G>T p.G190= | Silent (SNP) | VAF 64/575 reads (11%) | called by muse, mutect2, varscan2
- ZNF433 | c.1461C>T p.F487= | Silent (SNP) | VAF 42/392 reads (11%) | catalogued as COSV100794995; called by muse, mutect2, varscan2
- ACACA | c.6042-65G>T | Intron (SNP) | VAF 44/437 reads (10%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904478 G>A | 5'Flank (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- CDH11 | c.1895-653G>A | Intron (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- COL6A1 | c.1822+14T>C | Intron (SNP) | VAF 43/906 reads (5%) | called by muse, mutect2
- GALT | c.253-83T>G | Intron (SNP) | VAF 366/1207 reads (30%) | called by muse, mutect2, varscan2
- MLIP | c.613-12094T>A | Intron (SNP) | VAF 17/434 reads (4%) | called by muse, mutect2
- PTCD2 | c.127+21G>A | Intron (SNP) | VAF 28/435 reads (6%) | called by muse, mutect2
